Somatic mutation profile of tumor specimen TCGA-A5-A0G3-01A (aliquot TCGA-A5-A0G3-01A-11W-A062-09) from TCGA case TCGA-A5-A0G3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 61.4 years (22,421 days).
Specimen TCGA-A5-A0G3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3692ece3-bbbc-4e3d-80fe-62bb1dd1d5f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0G3-10A (Blood Derived Normal), aliquot TCGA-A5-A0G3-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4cd0a76-7878-47d6-b731-aa1b2f5bea1d

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, In Frame Del 1, Nonsense Mutation 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 73/84 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP2A1 | c.630G>A p.S210= | Splice Region (SNP) | VAF 26/45 reads (58%) | catalogued as rs563769160, COSV63921425; called by muse, mutect2, varscan2
- BCL2L11 | c.458G>C p.R153P (on ENST00000393256 / NM_138621.5; = p.R93P on NM_006538.5) | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58028974, COSV58030472; called by muse, mutect2
- C10orf62 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs771849333, COSV65705330; called by muse, mutect2, varscan2
- CASS4 | c.284A>G p.E95G | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV64386831; called by muse, mutect2, varscan2
- CEMIP2 | c.1930C>G p.R644G | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV65487760; called by muse, mutect2, varscan2
- CXorf66 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 69/397 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as COSV65169365; called by muse, mutect2, varscan2
- DDX10 | c.356A>G p.K119R | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59435814; called by muse, mutect2, varscan2
- DDX60 | c.3079C>A p.P1027T | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1459680987, COSV67097251; called by muse, mutect2, varscan2
- FECH | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs141888884; called by muse, mutect2, varscan2
- HHLA2 | c.280C>A p.L94I | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63317857; called by muse, mutect2, varscan2
- ITGB5 | c.1598G>A p.C533Y | Missense Mutation (SNP) | VAF 90/154 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56149907; called by muse, mutect2, varscan2
- ITGB6 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.999); catalogued as COSV51795323; called by muse, mutect2
- JCAD | c.2054G>C p.R685P | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV64760163; called by muse, mutect2, varscan2
- KRT1 | c.860T>A p.I287N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52867396; called by muse, mutect2, varscan2
- MYO10 | c.5526T>G p.Y1842* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV57023505; called by muse, mutect2, varscan2
- NFASC | c.1010C>T p.P337L (on ENST00000339876 / NM_001378329.1; = p.P348L on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58368416; called by muse, mutect2, varscan2
- OR52M1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 81/140 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs1003014199, COSV64171793; called by muse, mutect2, varscan2
- PCDHGA5 | c.1920G>T p.Q640H | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.443); catalogued as COSV53966638; called by muse, mutect2, varscan2
- PDE6A | c.950A>T p.K317M | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV54928291; called by muse, mutect2, varscan2
- PHYHIPL | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.07); catalogued as rs776129253, COSV65848467; called by muse, mutect2
- PLB1 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs748391028, COSV59821782; called by muse, mutect2, varscan2
- PLEKHH2 | c.3995C>T p.A1332V | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.07); catalogued as COSV56756043; called by muse, mutect2, varscan2
- RNF17 | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55042310; called by muse, mutect2, varscan2
- SLC35A4 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs770449710, COSV60052857; called by muse, mutect2, varscan2
- TBX20 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766895072, COSV101282386, COSV68784059; called by muse, mutect2, varscan2
- TNRC6B | c.3299G>A p.R1100Q (on ENST00000454349 / NM_001162501.2; = p.R1047Q on NM_015088.3) | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV57292445; called by muse, mutect2
- ZNF416 | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 6/156 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV52184843; called by muse, mutect2
- ZC3H6 | c.665_679del p.P222_K226del | In Frame Del (DEL) | VAF 35/72 reads (49%) | called by mutect2, pindel, varscan2
- ARSI | c.567C>T p.C189= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs112533194, COSV60817695; ClinVar: likely benign; called by muse, mutect2, varscan2
- GMPS | c.1326C>T p.G442= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs991508834, COSV55809110; called by muse, mutect2
- IFNW1 | c.258G>A p.Q86= | Silent (SNP) | VAF 7/170 reads (4%) | catalogued as COSV66522140; called by muse, mutect2
- MMP24 | c.270T>C p.Y90= | Silent (SNP) | VAF 80/144 reads (56%) | catalogued as COSV55770816; called by muse, mutect2, varscan2
- NAPSA | c.1032C>A p.I344= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV53797826; called by muse, mutect2, varscan2
- NYX | c.31C>T p.L11= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV61181085; called by muse, mutect2, varscan2
- PTPRT | c.2229C>T p.N743= | Silent (SNP) | VAF 123/199 reads (62%) | catalogued as COSV61989420; called by muse, mutect2, varscan2
- SMARCB1 | c.891G>A p.T297= (on ENST00000263121; = p.T343= on NM_003073.5) | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs761056928, COSV51955104; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- USF3 | c.1782C>G p.L594= | Silent (SNP) | VAF 111/307 reads (36%) | catalogued as COSV57074120; called by muse, mutect2, varscan2
- MIR1205 | n.48C>G | RNA (SNP) | VAF 14/442 reads (3%) | called by muse, mutect2
